Somatic mutation profile of tumor specimen TCGA-MP-A5C7-01A (aliquot TCGA-MP-A5C7-01A-11D-A25L-08) from TCGA case TCGA-MP-A5C7, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.7 years (28,015 days).
Specimen TCGA-MP-A5C7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a5fd931-fd5e-40c8-8110-0b66adf436b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A5C7-10A (Blood Derived Normal), aliquot TCGA-MP-A5C7-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/099f0c40-3daf-4dcc-81e1-c56898003f56

The open-access MAF lists 79 somatic variants for this specimen: 49 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 26, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, 3'UTR 1, Intron 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AICDA | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV57563841, COSV99983919; called by muse, mutect2, varscan2
- ALK | c.2995C>A p.P999T | Missense Mutation (SNP) | VAF 103/260 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV101202851; called by muse, mutect2, varscan2
- ARL8A | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99693438; called by muse, mutect2, varscan2
- CACNB1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100703663; called by muse, mutect2, varscan2
- CDX4 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100999165; called by muse, mutect2, varscan2
- CHID1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs747733825, COSV100060371; called by muse, mutect2, varscan2
- COL14A1 | c.3307A>G p.I1103V | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV99921073; called by muse, mutect2, varscan2
- DCAF12L2 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as COSV100758964; called by muse, mutect2, varscan2
- EMILIN2 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99599086; called by muse, mutect2, varscan2
- GPRC5B | c.1167+1G>A p.X389_splice | Splice Site (SNP) | VAF 84/179 reads (47%) | catalogued as COSV100245350; called by muse, mutect2, varscan2
- HIVEP2 | c.5831C>T p.S1944F | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV99177462; called by muse, mutect2, varscan2
- IGHG3 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs760926396; called by mutect2, varscan2
- KEAP1 | c.1035C>G p.Y345* | Nonsense Mutation (SNP) | VAF 12/15 reads (80%) | catalogued as COSV99408441; called by muse, mutect2, varscan2
- KIAA2026 | c.3874G>A p.V1292I | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101199272; called by muse, mutect2, varscan2
- LRP5 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM153244, COSV53711934, COSV99592861; called by muse, mutect2, varscan2
- LRRK2 | c.5842G>T p.E1948* | Nonsense Mutation (SNP) | VAF 43/118 reads (36%) | catalogued as COSV100111517; called by muse, mutect2, varscan2
- MED12 | c.3305C>A p.S1102Y | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100380486; called by muse, mutect2, varscan2
- NRXN3 | c.2389G>T p.A797S (on ENST00000335750 / NM_001330195.2; = p.A424S on NM_004796.6) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs779334109, COSV100210900; called by muse, mutect2, varscan2
- OR11H1 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1217821918, COSV99422091; called by mutect2, varscan2
- OR1A1 | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 118/267 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1455010628, COSV100410859; called by muse, mutect2, varscan2
- OR1A1 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 117/266 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100410790, COSV100410861; called by muse, mutect2, varscan2
- OR2AT4 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100532435; called by muse, mutect2, varscan2
- OR4C11 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100155590; called by muse, mutect2, varscan2
- OR56A4 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58112162; called by muse, mutect2, varscan2
- PKM | c.252T>A p.H84Q | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100065410; called by muse, mutect2, varscan2
- POLA1 | c.1635G>T p.K545N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100985883; called by muse, mutect2, varscan2
- PPP1R3C | c.81G>T p.R27S | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99491168; called by muse, mutect2, varscan2
- PPP3CA | c.1440T>G p.N480K | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548155, COSV59919008; called by muse, mutect2, varscan2
- PVALB | c.253A>T p.M85L | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99342976; called by muse, mutect2, varscan2
- RPTOR | c.3433C>T p.R1145W | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60806071; called by muse, mutect2, varscan2
- SCN2A | c.3689T>C p.I1230T | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs777751518, COSV99334074; called by muse, mutect2, varscan2
- SEC24A | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 160/219 reads (73%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs199957198; called by muse, mutect2, varscan2
- SLC17A7 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99677158; called by muse, mutect2, varscan2
- SMCO3 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.994); catalogued as COSV99660965; called by muse, mutect2, varscan2
- SOHLH2 | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101158012; called by muse, mutect2, varscan2
- STX6 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99276220; called by muse, mutect2, varscan2
- TNR | c.2126C>A p.A709D | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99692271; called by muse, mutect2, varscan2
- TRIML1 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV100206319, COSV100206430; called by muse, mutect2, varscan2
- USH2A | c.9388T>C p.W3130R | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs773132672, COSV100244509; called by muse, mutect2, varscan2
- WAPL | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV100077245; called by muse, mutect2, varscan2
- WDFY3 | c.8098A>G p.R2700G | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99886406; called by muse, mutect2, varscan2
- YIPF6 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101006292; called by muse, mutect2, varscan2
- ZNF440 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV100407804; called by muse, mutect2, varscan2
- ZNF804B | c.3028C>T p.H1010Y | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100307110; called by muse, mutect2, varscan2
- APC | c.1880dup p.N627Kfs*7 | Frame Shift Ins (INS) | VAF 26/52 reads (50%) | called by mutect2, pindel, varscan2
- CCT3 | c.1398_1399del p.R467Gfs*9 | Frame Shift Del (DEL) | VAF 29/158 reads (18%) | called by mutect2, pindel, varscan2
- HIF1A | c.134del p.P45Hfs*6 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.2131G>C p.D711H | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2
- UNC13C | c.5431dup p.M1811Nfs*3 | Frame Shift Ins (INS) | VAF 13/26 reads (50%) | called by mutect2, varscan2
- ABCB4 | c.756A>T p.A252= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as COSV99709652, COSV99711559; called by muse, mutect2, varscan2
- ADAM7 | c.528C>A p.T176= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV99445458; called by muse, mutect2, varscan2
- ASTN1 | c.273C>T p.Y91= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1433709650, COSV99923619; called by muse, mutect2, varscan2
- BRINP3 | c.1966C>A p.R656= | Silent (SNP) | VAF 86/391 reads (22%) | catalogued as COSV66522561, COSV66523061; called by muse, mutect2, varscan2
- CDH8 | c.1866C>T p.G622= | Silent (SNP) | VAF 61/126 reads (48%) | catalogued as COSV54857645; called by muse, mutect2, varscan2
- DNER | c.2079C>T p.A693= | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as COSV100520340; called by muse, mutect2, varscan2
- ERICH3 | c.1767T>C p.P589= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100446169; called by muse, mutect2, varscan2
- FGF12 | c.660A>G p.Q220= (on ENST00000454309 / NM_021032.5; = p.Q158= on NM_004113.6) | Silent (SNP) | VAF 101/260 reads (39%) | catalogued as COSV99284539; called by muse, mutect2, varscan2
- FNBP1 | c.735T>C p.I245= | Silent (SNP) | VAF 119/320 reads (37%) | catalogued as COSV100852868; called by muse, mutect2, varscan2
- FZD7 | c.756C>T p.F252= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as rs746990509, COSV99637545; called by muse, mutect2, varscan2
- HRNR | c.5856C>A p.G1952= | Silent (SNP) | VAF 122/1446 reads (8%) | catalogued as COSV100914062; called by muse, mutect2
- KIF21B | c.3045C>G p.S1015= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV100145356; called by muse, mutect2, varscan2
- LBR | c.1605A>G p.L535= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as CX031597, COSV99687831; called by muse, mutect2, varscan2
- MAGEB3 | c.588G>A p.R196= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100854609, COSV100854848; called by muse, mutect2
- MALSU1 | c.15C>T p.G5= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs575849724, COSV54978418; called by muse, mutect2, varscan2
- MAP3K19 | c.1725G>A p.P575= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as rs761415011, COSV100209496, COSV59643224; called by muse, mutect2, varscan2
- OR5L1 | c.675C>A p.I225= | Silent (SNP) | VAF 92/180 reads (51%) | catalogued as COSV100450355; called by muse, mutect2, varscan2
- PLXNB2 | c.3549G>T p.V1183= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100834327; called by muse, mutect2, varscan2
- PPTC7 | c.570C>T p.P190= | Silent (SNP) | VAF 58/166 reads (35%) | catalogued as COSV100845744, COSV62825805; called by muse, mutect2, varscan2
- RESF1 | c.3753A>G p.L1251= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs1358161769, COSV100440719; called by muse, mutect2, varscan2
- RICTOR | c.3813G>A p.T1271= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as rs774201167, COSV99704936; called by muse, mutect2, varscan2
- THSD7B | c.3123G>T p.L1041= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs538582414, COSV99759696; called by muse, mutect2, varscan2
- TRIM3 | c.1284G>A p.P428= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1564965466, COSV61984904; called by muse, mutect2, varscan2
- TRO | c.3747C>T p.F1249= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as rs1189857997, COSV99436030; called by muse, mutect2
- UNC5C | c.2208C>A p.G736= | Silent (SNP) | VAF 68/175 reads (39%) | catalogued as COSV71660890; called by muse, mutect2, varscan2
- VSIG2 | c.933G>A p.S311= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs931174330, COSV99423552; called by muse, mutect2, varscan2
- DNM1 | c.1672-1646C>A | Intron (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100360491; called by muse, mutect2, varscan2
- OR2A14 | c.*1G>T | 3'UTR (SNP) | VAF 72/182 reads (40%) | catalogued as COSV101376511; called by muse, mutect2, varscan2
- TMC6 | c.-1C>T | 5'UTR (SNP) | VAF 19/31 reads (61%) | catalogued as COSV100130522; called by muse, mutect2, varscan2
- TMEM183B | n.190C>T | RNA (SNP) | VAF 49/177 reads (28%) | catalogued as rs757522009; called by muse, mutect2, varscan2
